Somatic mutation profile of tumor specimen TCGA-A3-3363-01A (aliquot TCGA-A3-3363-01A-01D-0966-08) from TCGA case TCGA-A3-3363, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 50.9 years (18,596 days).
Specimen TCGA-A3-3363-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 723356b3-fd68-47e2-a884-0bea4efc687d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3363-11A (Solid Tissue Normal), aliquot TCGA-A3-3363-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8e409fe-ced3-41e0-8014-e497590540ca

The open-access MAF lists 48 somatic variants for this specimen: 40 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 6, Frame Shift Del 2, 3'Flank 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.3415C>T p.P1139S | Missense Mutation (SNP) | VAF 64/153 reads (42%) | SIFT tolerated (0.69); PolyPhen benign (0.024); catalogued as COSV61264126; called by muse, mutect2, varscan2
- ADGRF1 | c.2138T>A p.I713K | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51945774; called by muse, mutect2, varscan2
- ANKRD34A | c.838C>G p.L280V | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60161042; called by muse, mutect2, varscan2
- ANPEP | c.251C>A p.S84Y | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT tolerated (0.69); PolyPhen benign (0.119); catalogued as COSV55591881, COSV55595757; called by muse, mutect2
- ARID1B | c.3723G>A p.M1241I | Missense Mutation (SNP) | VAF 73/236 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV51663679; called by muse, mutect2, varscan2
- BORCS5 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 39/98 reads (40%) | catalogued as COSV53802829; called by muse, mutect2, varscan2
- CACNA1D | c.6447G>C p.E2149D (on ENST00000350061 / NM_001128840.3; = p.E2169D on NM_000720.4) | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.986); catalogued as COSV55448819, COSV55464333; called by muse, mutect2, varscan2
- CCDC14 | c.1822A>G p.K608E (on ENST00000488653; = p.K560E on NM_022757.5) | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV59945114; called by muse, mutect2
- CDC14A | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.005); catalogued as COSV60558746; called by muse, mutect2, varscan2
- CHD8 | c.2978T>C p.F993S (on ENST00000646647 / NM_001170629.2; = p.F714S on NM_020920.4) | Missense Mutation (SNP) | VAF 236/293 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67870715; called by muse, mutect2, varscan2
- CNOT1 | c.2834C>G p.P945R | Missense Mutation (SNP) | VAF 93/238 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.456); catalogued as COSV55317455; called by muse, mutect2, varscan2
- COL1A2 | c.2925T>A p.H975Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.031); catalogued as COSV51958984; called by muse, mutect2, varscan2
- CUBN | c.2906T>C p.L969P | Missense Mutation (SNP) | VAF 77/180 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV64716825; called by muse, mutect2, varscan2
- DNAH1 | c.3158T>C p.L1053P | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV70229532; called by muse, mutect2, varscan2
- DNAH7 | c.6976A>G p.I2326V | Missense Mutation (SNP) | VAF 81/192 reads (42%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.946); catalogued as COSV56767158; called by muse, mutect2, varscan2
- DYRK4 | c.237A>T p.K79N | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV50539759; called by muse, mutect2, varscan2
- GOLGA3 | c.665A>C p.K222T | Missense Mutation (SNP) | VAF 177/456 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.744); catalogued as COSV52632701; called by muse, mutect2, varscan2
- GPR155 | c.2353G>T p.D785Y | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55039268; called by muse, varscan2
- H4C5 | c.197T>C p.V66A | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as COSV63486752; called by muse, mutect2, varscan2
- IGSF9 | c.3277C>T p.P1093S (on ENST00000368094 / NM_001135050.2; = p.P1077S on NM_020789.4) | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.444); catalogued as COSV57422404; called by muse, mutect2, varscan2
- LMO7 | c.325A>G p.N109D (on ENST00000357063; = p.N124D on NM_005358.5) | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58537883; called by muse, mutect2, varscan2
- MPG | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 110/295 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs562548652, COSV54738476; called by muse, mutect2, varscan2
- NUCB2 | c.1040T>C p.L347P | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60375400; called by muse, mutect2
- OBSCN | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.837); catalogued as rs758692506, COSV52755492; called by muse, mutect2, varscan2
- PCDHA6 | c.2152T>C p.Y718H | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.91); catalogued as COSV65344467; called by muse, mutect2, varscan2
- PFAS | c.2304G>C p.W768C | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58980678; called by muse, mutect2, varscan2
- PRODH2 | c.233T>C p.L78P (on ENST00000301175; = p.L2P on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV56560035; called by muse, mutect2, varscan2
- RBM28 | c.1147T>G p.F383V | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56163291; called by muse, mutect2, varscan2
- RERE | c.3614C>T p.A1205V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.234); catalogued as rs764364709, COSV61942929; called by muse, mutect2, varscan2
- RHOB | c.101A>G p.Y34C | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV55356235; called by muse, mutect2, varscan2
- SCAF8 | c.650C>A p.P217H | Missense Mutation (SNP) | VAF 85/175 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1489934526, COSV65791991; called by muse, mutect2, varscan2
- SETDB1 | c.2077T>C p.C693R | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54983759; called by muse, mutect2, varscan2
- SNX13 | c.2774T>C p.F925S | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101296788; called by muse, mutect2, varscan2
- SRC | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 65/78 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV62440002; called by muse, mutect2, varscan2
- SUSD6 | c.302G>A p.S101N | Missense Mutation (SNP) | VAF 75/88 reads (85%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.947); catalogued as COSV61365540; called by muse, mutect2, varscan2
- TP53I3 | c.131T>C p.L44S | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV53187768; called by muse, mutect2, varscan2
- VAV2 | c.1538A>G p.N513S (on ENST00000371850 / NM_001134398.2; = p.N503S on NM_003371.4) | Missense Mutation (SNP) | VAF 71/168 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV64082219; called by muse, mutect2, varscan2
- WLS | c.1228A>G p.K410E | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52042176; called by muse, mutect2, varscan2
- ARHGAP11A | c.1557del p.M519Ifs*14 | Frame Shift Del (DEL) | VAF 52/139 reads (37%) | called by mutect2, pindel, varscan2
- TUBB | c.697_704del p.M233Cfs*14 | Frame Shift Del (DEL) | VAF 20/88 reads (23%) | called by pindel, varscan2
- CREB3 | c.1062A>G p.G354= | Silent (SNP) | VAF 91/274 reads (33%) | catalogued as COSV59207909; called by muse, mutect2, varscan2
- FREM1 | c.1348C>T p.L450= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV63087342; called by muse, mutect2, varscan2
- LRRCC1 | c.42G>T p.V14= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV64483597; called by muse, mutect2, varscan2
- PLCE1 | c.4804C>T p.L1602= | Silent (SNP) | VAF 43/110 reads (39%) | catalogued as COSV53352515; called by muse, mutect2, varscan2
- TMEM214 | c.669C>T p.I223= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs746591790, COSV53192834; called by muse, mutect2, varscan2
- UNC5CL | c.78T>C p.L26= | Silent (SNP) | VAF 53/125 reads (42%) | catalogued as rs750754440, COSV55110170; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.634A>G | RNA (SNP) | VAF 173/442 reads (39%) | called by muse, mutect2, varscan2
- TMEM167B | chr1:109100221 C>A | 3'Flank (SNP) | VAF 13/34 reads (38%) | catalogued as rs763731169; called by muse, mutect2, varscan2
